Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5KT, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5KT-01A (Primary Tumor).

[page 1 of 2]
Procedure: L adrenalectomy

Gross description: 7 x 6.3 x 5.3cm, 171gm

Diagnosis: adrenocortical carcinoma with myelolipomatous metaplasia

Reference Pathology:

Diagnosis: adrenocortical carcinoma with myelolipomatous metaplasia, KI67 20%, very unusual to encounter myelolipomatous metaplasia in a malignant tumor. However, proliferation rate clearly marks this as malignant

Weiss score: 2

Hough score: 1.69

Van Slooten score: 5.7

ICD-O-3

Carcinoma, adrenal cortical
8370/3

Site ① Adrenal Gland cortex
C74.0

gn 2/6/13

Process - if passes get more path -
if not malignant, hold shipping.

ICD/OA Discrepancy		

[page 2 of 2]
Patient # from Tissue Source Site

Date of report

Date of Surgery/specimen collection

Site (confirmed to be adrenal) with laterality indicated
Left

Tumor size(s)
10.5x8.5x5.5cm

Histologic diagnosis
ACC

Lymph Node Status
Unknown

Pathologic information
T2NxMx

Weiss score
2, but diagnosis of ACC by reference pathologist due to Ki67 20%

4/16/13. Per NCI, case
may ship as long as
it is ACC (regardless of stated
behavior).
BCK

Benign, per Weiss score of 2.
Shipping on hold: per 4/12/13

Source: NCI Genomic Data Commons file 51c6ad56-b563-41b1-b4c1-a54f4c6af15e (TCGA-OR-A5KT.7BE65565-0C63-466C-AE5D-A9B47BB354C9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).